Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6138, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6138-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

Right colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Cancer cecum

GROSS DESCRIPTION

Received fresh labeled "right colon" is a previously unopened 30 cm. segment of proximal right colon with attached 19 cm. of distal ileum surfaced by smooth scabrous tan pink serosa with a copious amount of attached mesocolon and mesentery. An unremarkable 3.9 cm. appendix averaging 0.5 cm. in diameter is present. The proximal and distal margins measures 4.5 and 8.0 cm. in circumference respectively. On opening there is a well circumscribed, 5.5 x 4.9 cm. rubbery white pink-red tumor immediately distal to the ileocecal valve. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. On sectioning, the tumor has a maximal thickness of 1.0 cm. and appears to extend into the muscularis and extend to within 1.2 cm. of the inked serosal surface. The ileal mucosa is unremarkable, tan-pink with regular folds and the walls average 0.5 cm. in thickness. A soft tan-pink colonic polyp is present measuring 0.2 cm. in greatest dimension, 11 cm. distal to the main tumor (see block 8). No additional mass lesion or abnormality is identified. Multiple soft to slightly rubbery pale tan tissues in keeping with lymph nodes measuring up to 1.3 cm. in greatest dimension are recovered from the attached mesocolon and mesentery. Tentative sections are submitted in 17 blocks as labeled.

[REDACTED]

BLOCK SUMMARY: 1 - Proximal and distal margins; 2 - tumor to inked free radial serosal surface; 3, 4 - central tumor; 5 - tumor to ICV; 6 - tumor to distal mucosa; 7 - random ileum; 8 - colon with small polyp; 9 - random colon; 10 - appendix; 11-13 - ile lymph nodes; 14-17 - one bisected lymph node per cassette. [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

This right hemicolectomy specimen contains a moderately differentiated adenocarcinoma of the cecum, involving the cecal side of the ileocecal valve. Please see the template below:

Histologic type: Adenocarcinoma.

Histologic grade: Moderately differentiated.

Primary tumor (pT): The tumor invades nearly the full thickness of the muscularis propria, (pT2).

Proximal margin: Negative for tumor.

Distal margin: Negative for tumor.

Circumferential (radial) margin: Negative for tumor.

Distance of tumor from closest margin: The tumor measures 1.2 cm

[page 2 of 2]
[REDACTED]

from the inked serosal surface and 19 cm from the proximal margin.

Vascular invasion: Negative.

Regional lymph nodes (pN): Twenty-four lymph nodes are found, all of which are negative for metastatic disease, 0/24 (pN0).

Non-lymph node pericolonic tumor: Negative.

Distant metastasis (pM): Cannot be assessed.

Other findings: A 2 mm adenomatous polyp is noted within the colon.

Ileum and appendix, no significant pathology.

DIAGNOSIS

Right colon, right hemicolectomy - Moderately-differentiated adenocarcinoma of the cecum extending into but not through the muscularis propria. No lymphatic invasion found and all twenty-four lymph nodes are negative for metastatic disease. All margins are negative for tumor. An incidental

2 mm adenomatous polyp is noted within the right colon.

Terminal ileum and appendix, no significant pathology.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 01b58c0c-84eb-4cb5-99f8-eff6ebcba199 (TCGA-A6-6138.270FF9CD-8154-4FAB-B2B5-01E9ACE89200.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).